Somatic mutation profile of cancer-model specimen HCM-BROD-0596-C43-85O (Adherent Cell Line, passage 8; aliquot HCM-BROD-0596-C43-85O-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0596-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.7 years (25,087 days).
Specimen HCM-BROD-0596-C43-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48e09e1c-fbc6-4cc8-a540-dae9577ad551.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0596-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0596-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/906e560d-e574-42f4-9af0-0c384267a71b

The open-access MAF lists 2,882 somatic variants for this specimen: 1,773 protein-altering or splice-affecting, 994 silent, 115 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,611, Silent 994, Nonsense Mutation 108, Intron 62, Splice Region 22, 5'Flank 14, 3'UTR 14, RNA 11, Splice Site 11, Frame Shift Del 8, 3'Flank 7, 5'UTR 6.

Variants (750 of 2,882; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4612C>T p.R1538* | Nonsense Mutation (SNP) | VAF 144/204 reads (71%) | catalogued as rs1411638309, COSV56852422; ClinVar: likely pathogenic; called by muse, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 183/275 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 193/457 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1554395411; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.3301G>A p.G1101R | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779439, CM1412704; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 308/484 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137852416, CM910128, COSV100812232; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GFAP | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 165/375 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs57661783, CM051052; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- GNAI2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 201/383 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs137853226, COSV56492973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 394/612 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917758, CM081303, COSV54240842; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MMUT | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs564069299, CM990882, COSV51272456, COSV51275106, COSV51281714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX11B | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 292/630 reads (46%) | catalogued as rs781984979, COSV65197176; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 174/359 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs193922770, CM971325, COSV62102500; ClinVar: pathogenic / drug response; called by muse, mutect2, varscan2
- AADACL2 | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 181/454 reads (40%) | catalogued as COSV62930159; called by muse, mutect2, varscan2
- AADACL3 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 258/542 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60200529; called by muse, mutect2
- AADACL4 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 198/379 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs375635678; called by muse, mutect2, varscan2
- AC008397.2 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 130/416 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53208262; called by muse, mutect2, varscan2
- AC099489.1 | c.5635G>A p.G1879S | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.125); catalogued as rs1294616792; called by muse, mutect2
- AC119396.1 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 232/324 reads (72%) | catalogued as rs1006176645; called by muse, mutect2, varscan2
- AC136428.1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 228/362 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs766270124, COSV101434973; called by muse, mutect2, varscan2
- ACSL6 | c.1453C>T p.P485S (on ENST00000379240; = p.P510S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/398 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.457); catalogued as rs867535797; called by muse, mutect2, varscan2
- ACSM1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 109/188 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSM2A | c.1679G>A p.R560Q (on ENST00000219054; = p.R481Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 233/364 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148142047; called by muse, mutect2, varscan2
- ACTA2 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as CM118490; called by muse, mutect2, varscan2
- ACTR1A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV64024400; called by muse, mutect2, varscan2
- ACTRT2 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 169/424 reads (40%) | catalogued as rs867646845, COSV65759371; called by muse, varscan2
- ADAM20 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 244/438 reads (56%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99833399; called by muse, mutect2, varscan2
- ADAM7 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 103/189 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751999467, COSV51534385; called by muse, mutect2, varscan2
- ADAM7 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 232/444 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV51534609; called by muse, mutect2, varscan2
- ADAM7 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 166/388 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV51535166; called by muse, mutect2, varscan2
- ADAMTS18 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 176/284 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs865936548, COSV51419356; called by muse, mutect2, varscan2
- ADAMTS2 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 297/690 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV52371211; called by muse, mutect2, varscan2
- ADAMTS20 | c.3119G>A p.G1040E | Missense Mutation (SNP) | VAF 141/236 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67139155, COSV99061796; called by muse, mutect2, varscan2
- ADAMTS20 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1270702920, COSV67129732; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3578G>A p.S1193N | Missense Mutation (SNP) | VAF 277/564 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV65890689; called by muse, mutect2, varscan2
- ADCY1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 162/304 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV52031960; called by muse, mutect2, varscan2
- ADCY8 | c.3010G>A p.G1004R | Missense Mutation (SNP) | VAF 207/419 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99650680; called by muse, mutect2, varscan2
- ADCY8 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 206/440 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV53900356; called by muse, mutect2, varscan2
- ADCYAP1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 158/336 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV52486068; called by muse, mutect2
- ADGRA3 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 119/258 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99293418; called by muse, mutect2, varscan2
- ADGRG4 | c.5563C>T p.P1855S | Missense Mutation (SNP) | VAF 308/482 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs777489023; called by muse, mutect2, varscan2
- ADGRG4 | c.6580C>T p.P2194S | Missense Mutation (SNP) | VAF 393/588 reads (67%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV54967263; called by muse, mutect2, varscan2
- ADGRG4 | c.7502C>T p.S2501L | Missense Mutation (SNP) | VAF 157/446 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV54950755; called by muse, mutect2, varscan2
- ADGRL1 | c.3641C>T p.S1214L (on ENST00000340736 / NM_001008701.3; = p.S1209L on NM_014921.5) | Missense Mutation (SNP) | VAF 93/306 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs746960334; called by muse, mutect2, varscan2
- ADGRL2 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 228/623 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54684247; called by muse, mutect2, varscan2
- ADGRV1 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 166/409 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs41305900; called by muse, mutect2, varscan2
- ADGRV1 | c.6779G>A p.R2260Q | Missense Mutation (SNP) | VAF 172/344 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs749204963, COSV101315594; called by muse, mutect2, varscan2
- AGRP | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs898112158; called by muse, mutect2, varscan2
- AIRE | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 263/489 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1030568996; called by muse, mutect2, varscan2
- AJAP1 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 207/436 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs769421868, COSV65451311; called by muse, mutect2, varscan2
- AK8 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 197/372 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV100050585; called by muse, mutect2, varscan2
- AKAP8L | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 173/377 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs1401623346; called by muse, mutect2, varscan2
- AL645922.1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 725/1202 reads (60%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs766612461; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- AMIGO2 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 142/393 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as COSV56974882; called by muse, mutect2, varscan2
- AMOTL2 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 283/470 reads (60%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs368269741; called by muse, mutect2, varscan2
- ANK1 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 172/349 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs1486547831; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7501C>T p.P2501S | Missense Mutation (SNP) | VAF 229/399 reads (57%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs145182659; called by muse, mutect2, varscan2
- ANKRD12 | c.5194C>A p.P1732T | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV100040913, COSV50819304; called by muse, mutect2, varscan2
- ANKRD12 | c.5195C>T p.P1732L | Missense Mutation (SNP) | VAF 134/284 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs756983904; called by muse, mutect2, varscan2
- ANKRD18A | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 253/552 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV68804774; called by muse, mutect2, varscan2
- ANKRD30A | c.391G>A p.D131N (on ENST00000611781; = p.D75N on NM_052997.2) | Missense Mutation (SNP) | VAF 196/197 reads (99%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1231002205, COSV64609015; called by muse, mutect2, varscan2
- ANKRD30A | c.2858G>A p.G953E (on ENST00000611781; = p.G897E on NM_052997.2) | Missense Mutation (SNP) | VAF 79/79 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs538383318, COSV64606658; called by muse, mutect2, varscan2
- ANKRD36C | c.2237C>A p.S746Y | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV54757281; called by muse, mutect2, varscan2
- ANKRD44 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 242/393 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99985541; called by muse, mutect2, varscan2
- ANO4 | c.950G>A p.R317Q (on ENST00000392977 / NM_001286615.2; = p.R282Q on NM_178826.4) | Missense Mutation (SNP) | VAF 154/254 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1202630749, COSV54594794; called by muse, varscan2
- ANO7 | c.1873G>A p.G625R (on ENST00000274979; = p.G571R on NM_001370694.2) | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1310969414; called by muse, mutect2, varscan2
- AOX1 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 218/369 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV65982781; called by muse, mutect2, varscan2
- APBA3 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 269/408 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1360096932; called by muse, mutect2, varscan2
- APC2 | c.6632C>T p.T2211I | Missense Mutation (SNP) | VAF 201/589 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs895565947; called by muse, mutect2, varscan2
- APCDD1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 327/634 reads (52%) | catalogued as rs373747410; called by muse, mutect2, varscan2
- APOB | c.9478G>A p.E3160K | Missense Mutation (SNP) | VAF 179/296 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs999346511, COSV51931380; called by muse, mutect2, varscan2
- APOB | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1047759477; called by muse, mutect2, varscan2
- AQP7 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 291/592 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770503247; called by muse, mutect2, varscan2
- ARAP2 | c.4859A>G p.D1620G | Missense Mutation (SNP) | VAF 248/550 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV58288092, COSV58289219; called by muse, mutect2
- ARHGAP21 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 161/184 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995838696, COSV100255684; called by muse, mutect2, varscan2
- ARHGEF1 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 176/362 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1348787604; called by muse, mutect2, varscan2
- ARHGEF12 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs1188291844; called by muse, mutect2, varscan2
- ARHGEF16 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 281/573 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1047293018; called by muse, varscan2
- ARID3B | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 300/453 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1352982253; called by muse, mutect2, varscan2
- ARIH2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 218/354 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62704889; called by muse, varscan2
- ARMC12 | c.1009A>G p.K337E (on ENST00000373866 / NM_001286574.2; = p.K364E on NM_145028.5) | Missense Mutation (SNP) | VAF 180/484 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.015); catalogued as rs950153284; called by muse, mutect2, varscan2
- ASPSCR1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 596/599 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1413238488; called by muse, mutect2, varscan2
- ASS1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs773150312; called by muse, mutect2, varscan2
- ASTN2 | c.1196G>A p.G399E (on ENST00000313400 / NM_001365069.1; = p.G348E on NM_014010.5) | Missense Mutation (SNP) | VAF 154/323 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV57796659; called by muse, mutect2, varscan2
- ASXL3 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 103/206 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs1440478761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11A | c.1026C>T p.F342= | Splice Region (SNP) | VAF 159/239 reads (67%) | catalogued as rs1387394606, COSV52124509; called by muse, mutect2, varscan2
- ATP13A4 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 72/361 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55070853; called by muse, mutect2, varscan2
- ATP13A4 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 70/358 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55068960; called by muse, mutect2, varscan2
- ATP1A3 | c.1201C>T p.H401Y (on ENST00000545399 / NM_001256214.2; = p.H388Y on NM_152296.5) | Missense Mutation (SNP) | VAF 165/342 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100131737; called by muse, mutect2, varscan2
- ATP1B4 | c.772C>T p.R258C (on ENST00000218008 / NM_001142447.3; = p.R254C on NM_012069.5) | Missense Mutation (SNP) | VAF 117/403 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as rs149447498, COSV54312900; called by muse, mutect2, varscan2
- ATP8B2 | c.2885C>T p.P962L (on ENST00000672630; = p.P929L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/329 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV59245782; called by muse, mutect2, varscan2
- ATPSCKMT | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 128/362 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs762541865; called by muse, mutect2, varscan2
- ATRX | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 93/405 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64874398; called by muse, mutect2, varscan2
- BBS4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 180/303 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1251827333; called by muse, mutect2, varscan2
- BCAT1 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 232/232 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1334431288; called by muse, mutect2, varscan2
- BCL11B | c.1789A>G p.K597E (on ENST00000357195 / NM_001282237.2; = p.K526E on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 252/570 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377444580; called by muse, mutect2, varscan2
- BCL11B | c.899G>C p.R300P (on ENST00000357195 / NM_001282237.2; = p.R229P on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 409/726 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99068898; called by muse, mutect2, varscan2
- BEST3 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 162/414 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs753618473; called by muse, mutect2, varscan2
- BEX5 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 202/589 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV61328355; called by muse, mutect2, varscan2
- BMPER | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 172/378 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.29); catalogued as COSV51832005; called by muse, mutect2
- BRAP | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 169/324 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100554104; called by muse, mutect2, varscan2
- BRINP1 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 237/464 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV56296860; called by muse, mutect2, varscan2
- BRINP1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 217/475 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV56303837, COSV56317776; called by muse, mutect2, varscan2
- BRINP3 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 256/476 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66513568; called by muse, varscan2
- BRS3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 130/458 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146164598, COSV101036705, COSV65710950; called by muse, mutect2, varscan2
- C11orf80 | c.892-7A>G | Splice Region (SNP) | VAF 238/371 reads (64%) | catalogued as rs769257397; called by muse, mutect2, varscan2
- C11orf95 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 349/512 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV58311394; called by muse, mutect2, varscan2
- C12orf50 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 128/343 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.889); catalogued as rs781126111; called by muse, mutect2, varscan2
- C12orf54 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 131/225 reads (58%) | catalogued as rs760341392, COSV58360190; called by muse, mutect2, varscan2
- C16orf46 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 105/376 reads (28%) | catalogued as rs145595395; called by muse, mutect2, varscan2
- C16orf78 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV54555053; called by muse, mutect2, varscan2
- C19orf47 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 163/378 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs151320497; called by muse, mutect2, varscan2
- C19orf81 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 205/436 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs959581840; called by muse, mutect2, varscan2
- C1orf131 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 181/480 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs779405167, COSV59642948; called by muse, mutect2, varscan2
- C1orf68 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 251/597 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as rs1000090998, COSV64224530; called by muse, mutect2, varscan2
- C22orf39 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs771216730; called by muse, mutect2, varscan2
- C6 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 130/294 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54708223; called by muse, mutect2, varscan2
- C6 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 182/322 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs369381506; called by muse, mutect2, varscan2
- C6orf132 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 588/1042 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as rs1233210366, COSV59375472; called by muse, mutect2, varscan2
- C9 | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 102/195 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54680663; called by muse, mutect2, varscan2
- CABP1 | c.802G>A p.E268K (on ENST00000316803 / NM_001033677.1; = p.E65K on NM_004276.5) | Missense Mutation (SNP) | VAF 144/335 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1328676871, COSV56458203; called by muse, mutect2, varscan2
- CACNA1B | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 385/729 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1292482427, COSV53115294; called by muse, mutect2, varscan2
- CACNA1E | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 263/492 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs551308908; called by muse, mutect2, varscan2
- CACNG3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 180/274 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV50063920; called by muse, mutect2, varscan2
- CADM2 | c.241C>T p.R81C (on ENST00000407528 / NM_001167674.2; = p.R83C on NM_153184.4) | Missense Mutation (SNP) | VAF 162/384 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs139991481, COSV67406856; called by muse, mutect2, varscan2
- CADPS2 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 151/328 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57364024; called by muse, mutect2, varscan2
- CAPN10 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 228/373 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867854825, COSV54377409; called by muse, mutect2, varscan2
- CARD6 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 127/300 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.413); catalogued as COSV99620391; called by muse, mutect2, varscan2
- CARD6 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 156/407 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV54565204; called by muse, mutect2, varscan2
- CARD9 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 163/380 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs757521707; called by muse, mutect2, varscan2
- CATSPER1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 310/488 reads (64%) | SIFT tolerated (0.67); PolyPhen benign (0.078); catalogued as COSV56411379; called by muse, mutect2, varscan2
- CBLB | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51424023; called by muse, mutect2, varscan2
- CCDC136 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 209/428 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV52798951; called by muse, mutect2, varscan2
- CCDC141 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 125/382 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs865980981, COSV55377174; called by muse, mutect2, varscan2
- CCDC168 | c.18253A>G p.R6085G | Missense Mutation (SNP) | VAF 147/348 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV100487624; called by muse, mutect2
- CCDC27 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 228/433 reads (53%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.092); catalogued as COSV53902807; called by muse, mutect2, varscan2
- CCDC39 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM131302; called by muse, mutect2, varscan2
- CCDC60 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 119/210 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs576781017, COSV59546324; called by muse, mutect2, varscan2
- CCDC73 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs868393270, COSV100067237, COSV58797856; called by muse, mutect2, varscan2
- CCDC85A | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 79/299 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs765502186, COSV101339350, COSV68149842; called by muse, mutect2, varscan2
- CCDC88C | c.4792C>T p.R1598W | Missense Mutation (SNP) | VAF 237/435 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57797256; called by muse, mutect2, varscan2
- CCNB3 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 295/295 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs782348453; called by muse, mutect2, varscan2
- CCSER1 | c.1729C>T p.L577F | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV61415369; called by muse, mutect2, varscan2
- CCT2 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs747101634; called by muse, mutect2, varscan2
- CD163L1 | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 312/313 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV58011409; called by muse, mutect2, varscan2
- CD163L1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 261/263 reads (99%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV58021540; called by muse, mutect2, varscan2
- CD19 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346128809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD34 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 236/549 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60413657; called by muse, mutect2, varscan2
- CD86 | c.265G>A p.D89N (on ENST00000330540 / NM_175862.5; = p.D83N on NM_006889.4) | Missense Mutation (SNP) | VAF 228/396 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as COSV100053945; called by muse, varscan2
- CDH20 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 270/609 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs138127688, COSV53015177; called by muse, mutect2, varscan2
- CDH6 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 180/437 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV54063505; called by muse, mutect2, varscan2
- CDK10 | c.254G>A p.R85Q (on ENST00000353379 / NM_052988.5; = p.R14Q on NM_052987.4) | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757712230, COSV57045975; called by muse, mutect2, varscan2
- CDK9 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 168/338 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs751991570, COSV64723870; called by muse, mutect2, varscan2
- CDKL5 | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 223/224 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs764423452; called by muse, mutect2, varscan2
- CELSR1 | c.8414C>T p.S2805F | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs755549263, COSV53086670; called by muse, mutect2, varscan2
- CELSR1 | c.5263G>A p.G1755S | Missense Mutation (SNP) | VAF 172/330 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs745985122, COSV53087180, COSV53098535; called by muse, mutect2, varscan2
- CFAP43 | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV63852778; called by muse, mutect2, varscan2
- CFAP54 | c.4352G>A p.R1451Q | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.138); catalogued as rs773999946, COSV61574963; called by muse, mutect2, varscan2
- CFAP54 | c.6471G>A p.M2157I | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV61573023; called by muse, mutect2, varscan2
- CFAP74 | c.1349T>G p.L450* | Nonsense Mutation (SNP) | VAF 406/657 reads (62%) | catalogued as COSV54567702; called by muse, mutect2, varscan2
- CFAP91 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 250/418 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs747341452, COSV56340952; called by muse, mutect2, varscan2
- CFHR1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 180/415 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV57626219; called by muse, mutect2, varscan2
- CFHR4 | c.1273G>A p.G425R (on ENST00000367416 / NM_001201551.2; = p.G179R on NM_006684.5) | Missense Mutation (SNP) | VAF 206/420 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV99259324; called by muse, varscan2
- CFHR5 | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 107/282 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs753176414; called by muse, mutect2, varscan2
- CFTR | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 153/356 reads (43%) | catalogued as CM941971, COSV50041069; called by muse, mutect2, varscan2
- CFTR | c.1792A>G p.K598E | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs397508302, CD972127, CM066545, CM067741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD1 | c.4437G>A p.W1479* | Nonsense Mutation (SNP) | VAF 37/140 reads (26%) | catalogued as rs1329235381, COSV99399883; called by muse, mutect2, varscan2
- CHD4 | c.3145C>T p.L1049F (on ENST00000357008 / NM_001363606.2; = p.L1062F on NM_001273.5) | Missense Mutation (SNP) | VAF 207/207 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100537149; called by muse, mutect2, varscan2
- CHD5 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 162/357 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV52412005; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 109/265 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, mutect2, varscan2
- CHRD | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 179/491 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52608219; called by muse, mutect2
- CHRDL2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 105/338 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.375); catalogued as rs536498622, COSV55225561; called by muse, mutect2, varscan2
- CHRM3 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 219/460 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382696054, COSV55089720; called by muse, mutect2, varscan2
- CIART | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 134/330 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs139897151; called by muse, mutect2, varscan2
- CIC | c.3097G>A p.G1033R | Missense Mutation (SNP) | VAF 284/566 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); catalogued as rs767155091; called by muse, varscan2
- CLCN6 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 204/452 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs373167140; called by muse, mutect2, varscan2
- CLEC5A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 130/289 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1197523757, COSV69397002; called by muse, mutect2, varscan2
- CLUAP1 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 251/392 reads (64%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs143126195; called by muse, mutect2, varscan2
- CMYA5 | c.4865C>T p.P1622L | Missense Mutation (SNP) | VAF 238/421 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs200982295; called by muse, mutect2, varscan2
- CNGB3 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as rs1184824947, COSV60688088; called by muse, mutect2, varscan2
- CNNM4 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 167/272 reads (61%) | catalogued as rs1021713187, CM090738, COSV65660159; called by muse, mutect2, varscan2
- CNTN5 | c.325A>C p.I109L | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54275975; called by muse, mutect2, varscan2
- CNTN5 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1436874415, COSV54275052, COSV99681181; called by muse, mutect2, varscan2
- CNTNAP5 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373323066; called by muse, mutect2, varscan2
- COL11A1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 186/533 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62185672, COSV62193987; called by muse, mutect2, varscan2
- COL14A1 | c.5288C>T p.S1763L | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as COSV52865949; called by muse, varscan2
- COL18A1 | c.2228C>T p.T743I (on ENST00000359759 / NM_130444.3; = p.T508I on NM_030582.4) | Missense Mutation (SNP) | VAF 117/511 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs1427568442, COSV62706007; called by muse, mutect2, varscan2
- COL19A1 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs760925220, COSV59570978; called by muse, mutect2, varscan2
- COL21A1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 352/574 reads (61%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as rs867948640, COSV55159384; called by mutect2, varscan2
- COL21A1 | c.1650+1G>A p.X550_splice | Splice Site (SNP) | VAF 293/504 reads (58%) | catalogued as rs767901816; called by muse, mutect2, varscan2
- COL22A1 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 201/404 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57339199; called by muse, mutect2, varscan2
- COL3A1 | c.2104G>A p.G702S | Missense Mutation (SNP) | VAF 224/330 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1512423; called by muse, mutect2, varscan2
- COL4A4 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 187/540 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs762822768, COSV61633794; called by muse, mutect2, varscan2
- COL4A5 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 115/366 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1437156555, COSV60374220; called by muse, mutect2, varscan2
- COL5A3 | c.4010G>A p.G1337E | Missense Mutation (SNP) | VAF 232/390 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868047902, COSV53418128; called by muse, mutect2, varscan2
- COL6A5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 150/351 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV55201496; called by muse, mutect2, varscan2
- CPA3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 109/195 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56045717; called by muse, mutect2, varscan2
- CPA3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 165/437 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as rs867230201, COSV56045225; called by muse, mutect2, varscan2
- CPA4 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 168/401 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55985487; called by muse, mutect2, varscan2
- CPLX4 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 183/378 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs781137378; called by muse, mutect2, varscan2
- CPNE4 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs751105787; called by muse, mutect2, varscan2
- CPNE6 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 233/451 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV53746466; called by muse, mutect2, varscan2
- CPZ | c.1699A>G p.I567V (on ENST00000360986 / NM_001014447.3; = p.I556V on NM_003652.3) | Missense Mutation (SNP) | VAF 230/500 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.039); catalogued as rs527836142; called by muse, mutect2, varscan2
- CR2 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 242/480 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV65506420; called by muse, mutect2, varscan2
- CRYBG2 | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 127/404 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs955274470; called by muse, mutect2, varscan2
- CSF1R | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1411349452; called by muse, mutect2, varscan2
- CSF2RA | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 237/479 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1181481612, COSV100817746; called by muse, mutect2, varscan2
- CSMD1 | c.7508G>A p.G2503E (on ENST00000520002; = p.G2502E on NM_033225.6) | Missense Mutation (SNP) | VAF 141/296 reads (48%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.999); catalogued as COSV59310410; called by muse, mutect2, varscan2
- CSMD1 | c.6491C>T p.P2164L (on ENST00000520002; = p.P2163L on NM_033225.6) | Missense Mutation (SNP) | VAF 200/400 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772713616; called by muse, mutect2, varscan2
- CSMD1 | c.5104G>A p.E1702K (on ENST00000520002; = p.E1701K on NM_033225.6) | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV59355311; called by muse, varscan2
- CSMD1 | c.5103G>A p.G1701= (on ENST00000520002; = p.G1700= on NM_033225.6) | Splice Region (SNP) | VAF 81/171 reads (47%) | catalogued as rs909928261, COSV59308408; called by muse, varscan2
- CSMD1 | c.933G>A p.V311= | Splice Region (SNP) | VAF 189/397 reads (48%) | catalogued as rs376995728; called by muse, mutect2, varscan2
- CSMD3 | c.9148+1G>A p.X3050_splice (on ENST00000297405 / NM_001363185.1; = p.X2881_splice on NM_052900.3) | Splice Site (SNP) | VAF 138/260 reads (53%) | catalogued as rs200499629, COSV52105444; called by muse, mutect2, varscan2
- CSMD3 | c.1477G>A p.E493K (on ENST00000297405 / NM_001363185.1; = p.E389K on NM_052900.3) | Missense Mutation (SNP) | VAF 162/320 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52318007; called by muse, mutect2, varscan2
- CTNNBL1 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 151/322 reads (47%) | catalogued as COSV63746696; called by muse, mutect2, varscan2
- CYLC2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 241/497 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV66336737, COSV66337270; called by muse, mutect2, varscan2
- CYLC2 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 237/476 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs369079750; called by muse, mutect2, varscan2
- CYP2A7 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 262/584 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502356; called by muse, mutect2, varscan2
- CYP3A4 | c.1484C>T p.S495F (on ENST00000336411; = p.S464F on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/383 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs768323664; called by muse, mutect2, varscan2
- CYP3A43 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 165/364 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV55936966; called by muse, mutect2, varscan2
- CYP4A11 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 112/325 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV60224482; called by muse, mutect2, varscan2
- CYP4B1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 182/295 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1047656596, COSV54724199; called by muse, mutect2, varscan2
- CYP4X1 | c.1355G>A p.R452K | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64150816; called by muse, mutect2, varscan2
- CYP4Z1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV100497855, COSV100497985; called by muse, varscan2
- CYTH4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 125/339 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs865913340, COSV50635280; called by muse, mutect2, varscan2
- DAB1 | c.1265C>T p.T422I (on ENST00000371231; = p.T389I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 249/501 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1557545640, COSV64692713; called by muse, mutect2, varscan2
- DCHS1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 118/444 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs780012886; called by muse, mutect2, varscan2
- DCUN1D3 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 226/334 reads (68%) | catalogued as COSV60953014; called by muse, mutect2, varscan2
- DENND2C | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 154/401 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs772944552, COSV67920142; called by muse, mutect2, varscan2
- DEUP1 | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as rs751323249, COSV53212101; called by muse, mutect2
- DGKI | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 173/392 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365470441; called by muse, mutect2, varscan2
- DHX34 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 211/412 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1170484982; called by muse, mutect2, varscan2
- DIAPH3 | c.1706G>A p.G569E (on ENST00000400324 / NM_001042517.2; = p.G306E on NM_030932.3) | Missense Mutation (SNP) | VAF 196/356 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs776635573; called by muse, mutect2, varscan2
- DLG5 | c.2461C>T p.R821* | Nonsense Mutation (SNP) | VAF 325/325 reads (100%) | catalogued as COSV64948372; called by muse, mutect2, varscan2
- DMBT1 | c.1784-1G>A p.X595_splice | Splice Site (SNP) | VAF 308/309 reads (100%) | catalogued as COSV100352470; called by muse, mutect2, varscan2
- DNAH10 | c.388C>T p.P130S (on ENST00000409039; = p.P69S on NM_207437.3) | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as COSV68993374; called by muse, mutect2, varscan2
- DNAH11 | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs371235859, COSV100177434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH14 | c.6139G>A p.E2047K (on ENST00000445597; = p.E2700K on NM_001367479.1) | Missense Mutation (SNP) | VAF 203/539 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1156837640, COSV59894733; called by muse, mutect2, varscan2
- DNAH2 | c.7103C>T p.S2368L | Missense Mutation (SNP) | VAF 349/350 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs148494854, COSV66720502; called by muse, mutect2, varscan2
- DNAH2 | c.10277G>A p.R3426Q | Missense Mutation (SNP) | VAF 368/369 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as rs201968584; called by muse, mutect2, varscan2
- DNAH3 | c.8263G>A p.E2755K | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759835468, COSV54509344; called by muse, mutect2, varscan2
- DNAH3 | c.4547G>A p.G1516E | Missense Mutation (SNP) | VAF 111/359 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1190131377; called by muse, mutect2, varscan2
- DNAH3 | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 139/214 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as rs541368919, COSV54529378; called by muse, mutect2, varscan2
- DNAH5 | c.11074C>T p.L3692F | Missense Mutation (SNP) | VAF 202/359 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1382261599; called by muse, mutect2, varscan2
- DNAH5 | c.8882G>A p.G2961E | Missense Mutation (SNP) | VAF 180/343 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54256658; called by muse, mutect2, varscan2
- DNAH5 | c.5498G>A p.G1833E | Missense Mutation (SNP) | VAF 153/284 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867913207; called by muse, mutect2, varscan2
- DNAH6 | c.6182G>A p.R2061Q | Missense Mutation (SNP) | VAF 231/322 reads (72%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as rs765469238, CM162785; called by muse, mutect2, varscan2
- DNAH6 | c.6392C>T p.S2131L | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs867327643; called by muse, mutect2, varscan2
- DNAH7 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 194/329 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56788901; called by muse, mutect2, varscan2
- DNAH7 | c.3832C>T p.H1278Y | Missense Mutation (SNP) | VAF 121/192 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV56771861; called by muse, mutect2, varscan2
- DNAH8 | c.7514G>A p.R2505Q | Missense Mutation (SNP) | VAF 122/371 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330298296, COSV59428426; called by muse, mutect2, varscan2
- DNAH8 | c.12947C>T p.S4316L | Missense Mutation (SNP) | VAF 176/606 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765766734, COSV59443932; called by muse, mutect2, varscan2
- DNAH9 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 173/174 reads (99%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs1443985595, COSV52335653; called by muse, mutect2, varscan2
- DNAJB13 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 177/277 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV60269539; called by muse, mutect2, varscan2
- DNALI1 | c.424A>C p.I142L (on ENST00000296218; = p.I120L on NM_003462.5) | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as rs1227767571; called by muse, mutect2, varscan2
- DNMT3B | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs749197342, COSV52415308; called by muse, mutect2, varscan2
- DOCK2 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 154/289 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1360509769, COSV56947114, COSV56971412; called by muse, mutect2
- DOCK4 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 74/329 reads (22%) | catalogued as rs374816878; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 259/700 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DRD2 | c.1137C>T p.L379= | Splice Region (SNP) | VAF 89/232 reads (38%) | catalogued as rs752872204, COSV60763426; called by muse, mutect2, varscan2
- DSC1 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 256/545 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57145311; called by muse, mutect2, varscan2
- DSC1 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 220/460 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs267605150, COSV99937667; called by muse, mutect2, varscan2
- DSC3 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 204/406 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV64572936, COSV64575730; called by muse, mutect2, varscan2
- DSCAM | c.3658C>T p.R1220* | Nonsense Mutation (SNP) | VAF 166/338 reads (49%) | catalogued as rs867787586; called by muse, mutect2, varscan2
- DSCAM | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101261371, COSV68033183; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 278/584 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DSG2 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 195/410 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99852704; called by muse, mutect2, varscan2
- DZIP1L | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 282/473 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV59519783; called by muse, mutect2, varscan2
- EBF1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 256/457 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs750855534; called by muse, mutect2, varscan2
- EBF2 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs751281440, COSV68776087; called by muse, varscan2
- EDAR | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 127/360 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.257); catalogued as COSV51502478; called by muse, mutect2, varscan2
- EFEMP1 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs781708447; called by muse, mutect2, varscan2
- EFHB | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 123/325 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV55544595; called by muse, mutect2, varscan2
- EGR3 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 292/544 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV100416289; called by muse, mutect2, varscan2
- EHMT1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 224/504 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs727503916; ClinVar: uncertain significance; called by muse, mutect2
- EHMT1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 224/504 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1389665235; called by muse, mutect2
- ELF4 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 228/689 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs954660673; called by muse, mutect2, varscan2
- EMB | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV57480294; called by muse, mutect2, varscan2
- ENAM | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 267/268 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs868759180, COSV68535291; called by muse, mutect2, varscan2
- EPAS1 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 170/480 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.101); catalogued as COSV55391640; called by muse, mutect2, varscan2
- EPB41L1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 121/560 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754822027, COSV52435165; called by muse, mutect2, varscan2
- ERF | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 311/656 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1219051518; called by muse, mutect2, varscan2
- ESM1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260213119, COSV101195624; called by muse, mutect2, varscan2
- ESR2 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 200/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371856990; called by muse, mutect2, varscan2
- ESRRB | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 382/742 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1477346091, COSV55062198; ClinVar: uncertain significance; called by muse, varscan2
- EVA1C | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 276/567 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55827554; called by muse, mutect2, varscan2
- EXOC4 | c.2914A>T p.T972S | Missense Mutation (SNP) | VAF 115/240 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV54109506; called by muse, mutect2, varscan2
- EXPH5 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 133/416 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs533686338; called by muse, mutect2, varscan2
- FADS6 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 131/531 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1247592363, COSV100044033; called by muse, mutect2, varscan2
- FAM135B | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 222/418 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as rs370460671, COSV52731262; called by muse, mutect2, varscan2
- FAM13C | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 194/195 reads (99%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV53252796, COSV99513849; called by muse, mutect2, varscan2
- FAM170A | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 169/300 reads (56%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.974); catalogued as rs750816456; called by muse, mutect2, varscan2
- FAM193A | c.2692C>T p.Q898* | Nonsense Mutation (SNP) | VAF 236/500 reads (47%) | catalogued as COSV61198524; called by muse, mutect2, varscan2
- FAM221B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 196/378 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65073698; called by muse, mutect2
- FAM227B | c.1415A>C p.K472T | Missense Mutation (SNP) | VAF 151/222 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs1370229064, COSV54815190; called by muse, mutect2, varscan2
- FAM3D | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs761002325, COSV62559043; called by muse, mutect2, varscan2
- FAM47A | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 357/357 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs1435553467, COSV100650088, COSV60499376; called by muse, mutect2, varscan2
- FAM47C | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 460/466 reads (99%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.687); catalogued as rs375607348, COSV63728240; called by muse, mutect2, varscan2
- FAM83G | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 456/458 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV100524817; called by muse, mutect2, varscan2
- FAM90A1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 256/576 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562876348, COSV56710170; called by muse, mutect2, varscan2
- FASN | c.4913C>T p.S1638F | Missense Mutation (SNP) | VAF 449/449 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV100148252; called by muse, mutect2, varscan2
- FAT4 | c.9619G>A p.E3207K | Missense Mutation (SNP) | VAF 198/199 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868613088, COSV58715034; called by muse, mutect2, varscan2
- FAT4 | c.10799G>A p.G3600E | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58678321; called by muse, mutect2, varscan2
- FBLN5 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 151/368 reads (41%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV50903550; called by muse, mutect2, varscan2
- FCHO1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 217/340 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs530821806, COSV53183133; called by muse, mutect2
- FGD2 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 254/745 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs761063246, COSV99236708; called by muse, mutect2, varscan2
- FGFBP1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 231/434 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs754608281, COSV99468902; called by muse, mutect2, varscan2
- FGFR3 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 276/587 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs751042118; called by muse, mutect2, varscan2
- FLG | c.10607G>A p.G3536E | Missense Mutation (SNP) | VAF 300/599 reads (50%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.874); catalogued as rs1279541481, COSV64240112; called by muse, varscan2
- FLG | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 374/727 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs754426329; called by muse, varscan2
- FLG | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 268/630 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.167); catalogued as rs369474474, COSV64243153; called by muse, varscan2
- FLNA | c.4576G>A p.G1526R | Missense Mutation (SNP) | VAF 166/481 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs201823071, CM1511657; called by muse, mutect2, varscan2
- FLNC | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 166/361 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs760911646, COSV57962877; called by muse, varscan2
- FLT1 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 249/427 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV56723292; called by muse, mutect2, varscan2
- FLVCR2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 276/521 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as rs778286255, COSV53163029, COSV99471131; called by muse, mutect2, varscan2
- FMN2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 349/810 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs755620586, COSV60457466; called by muse, mutect2, varscan2
- FMN2 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.324); catalogued as rs1479970087, COSV100145528; called by muse, mutect2, varscan2
- FMNL2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 111/202 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56490889; called by muse, mutect2, varscan2
- FMR1 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 249/364 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503710, COSV99503872; called by muse, mutect2, varscan2
- FNDC3A | c.938C>T p.S313L (on ENST00000492622 / NM_001079673.2; = p.S257L on NM_014923.5) | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101001325; called by muse, mutect2, varscan2
- FRAS1 | c.3329C>T p.S1110F | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756919344; called by muse, mutect2, varscan2
- FRMD4B | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 150/369 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV68331564; called by muse, mutect2, varscan2
- FRMPD3 | c.4499C>T p.A1500V | Missense Mutation (SNP) | VAF 314/520 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV99346962; called by muse, varscan2
- FRYL | c.8237C>T p.S2746F | Missense Mutation (SNP) | VAF 231/430 reads (54%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.961); catalogued as rs780732528, COSV99977143; called by muse, mutect2, varscan2
- FSIP2 | c.7940C>T p.P2647L | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1268739398; called by muse, mutect2, varscan2
- FSTL5 | c.348A>T p.R116S | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV104401727; called by muse, mutect2, varscan2
- GABRA2 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 151/315 reads (48%) | catalogued as rs748381199; called by muse, mutect2, varscan2
- GABRA5 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 226/350 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1365550701; called by muse, mutect2, varscan2
- GAL3ST4 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 286/591 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.473); catalogued as rs540539176; called by muse, mutect2, varscan2
- GALNT10 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as rs370969922, COSV51726166; called by muse, mutect2, varscan2
- GALNT13 | c.858G>A p.R286= | Splice Region (SNP) | VAF 143/210 reads (68%) | catalogued as COSV101222170, COSV67233749; called by muse, mutect2, varscan2
- GALNT13 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 129/212 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV67211781; called by muse, mutect2, varscan2
- GALP | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 187/398 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs867751771, COSV61999251; called by muse, mutect2, varscan2
- GBE1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101450149; called by muse, mutect2, varscan2
- GBP2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 164/275 reads (60%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as rs781516751; called by muse, mutect2, varscan2
- GDPD2 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 257/436 reads (59%) | catalogued as COSV65532682; called by muse, mutect2, varscan2
- GGA3 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 262/568 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99821723; called by muse, mutect2, varscan2
- GGT5 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 155/389 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1218880099, COSV99571366; called by muse, mutect2, varscan2
- GGT5 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 183/443 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV54070076; called by muse, mutect2, varscan2
- GJA1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 178/313 reads (57%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.646); catalogued as rs1265740574, COSV56997529; called by muse, mutect2, varscan2
- GLI2 | c.4486G>A p.D1496N (on ENST00000361492 / NM_001374353.1; = p.D1513N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 282/451 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs755563767, COSV58033899; called by muse, mutect2, varscan2
- GLYAT | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 196/312 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53538375; called by muse, mutect2, varscan2
- GOLGA4 | c.4150C>T p.Q1384* | Nonsense Mutation (SNP) | VAF 169/383 reads (44%) | catalogued as COSV62710265; called by muse, mutect2, varscan2
- GOLGA8S | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1190506399, COSV73788191; called by muse, mutect2, varscan2
- GPR32 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 246/522 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54514279; called by muse, mutect2, varscan2
- GPRC6A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 290/290 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369734914, COSV59953059; called by muse, mutect2, varscan2
- GRIN2A | c.4090G>A p.D1364N | Missense Mutation (SNP) | VAF 116/367 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1245573153, COSV58022910; called by muse, mutect2, varscan2
- GRIN2A | c.2852G>A p.G951E | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV58029542; called by muse, mutect2, varscan2
- GRIP1 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99671277; called by muse, mutect2, varscan2
- GRM7 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 160/438 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV63158538; called by muse, mutect2, varscan2
- GRXCR1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 223/447 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs778774192, COSV67670223; called by muse, mutect2, varscan2
- GSDMC | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV52697840; called by muse, mutect2, varscan2
- GSTA2 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 291/486 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV72415254; called by muse, mutect2, varscan2
- HARS2 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.936); catalogued as rs1401967821; called by muse, mutect2, varscan2
- HAUS7 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 169/488 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs782807039, COSV57849402; called by muse, mutect2, varscan2
- HAUS7 | c.342C>A p.H114Q | Missense Mutation (SNP) | VAF 168/485 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV57848660; called by muse, mutect2, varscan2
- HAVCR1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 223/401 reads (56%) | catalogued as COSV59397432, COSV59401595; called by muse, mutect2, varscan2
- HCN3 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 375/854 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.339); catalogued as rs1413271531; called by muse, mutect2, varscan2
- HGD | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866380660; called by muse, mutect2, varscan2
- HHIPL2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 298/520 reads (57%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV58566285; called by muse, mutect2, varscan2
- HIVEP1 | c.6821C>T p.P2274L | Missense Mutation (SNP) | VAF 340/610 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs770790070; called by muse, mutect2, varscan2
- HMCN2 | c.13231G>T p.V4411L | Missense Mutation (SNP) | VAF 284/579 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV70934715; called by muse, mutect2, varscan2
- HOXB5 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.663); catalogued as rs1276718933, COSV99494340; called by muse, mutect2, varscan2
- HS3ST1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 180/409 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1270148575; called by muse, mutect2, varscan2
- HS6ST2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 231/349 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs866391579, COSV63711877; called by muse, mutect2, varscan2
- HSF4 | c.1022C>T p.P341L (on ENST00000521374 / NM_001040667.3; = p.P311L on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 239/386 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1206776401; called by muse, mutect2, varscan2
- HTR2C | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 140/505 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1251816359, COSV52203430, COSV52215308; called by muse, varscan2
- HYDIN | c.13642C>T p.R4548C | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs201203817, COSV101125081; called by muse, mutect2, varscan2
- HYDIN | c.10639G>A p.E3547K | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.442); catalogued as COSV66858470; called by muse, mutect2, varscan2
- IGDCC4 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 168/494 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.054); catalogued as COSV100733200, COSV61535523; called by muse, mutect2, varscan2
- IGHG3 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 373/678 reads (55%) | catalogued as rs1566732422; called by muse, mutect2, varscan2
- IGHV3-23 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 199/643 reads (31%) | catalogued as rs1164728836; called by muse, mutect2, varscan2
- IGHV3-23 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 105/449 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.296); catalogued as rs782495642; called by muse, mutect2, varscan2
- IGHV3-53 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 188/412 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as rs782504417; called by muse, mutect2, varscan2
- IGKV3OR2-268 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs1396199636; called by muse, mutect2, varscan2
- IGLV11-55 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 162/295 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772200742; called by muse, mutect2, varscan2
- IGSF10 | c.5925G>A p.W1975* | Nonsense Mutation (SNP) | VAF 63/443 reads (14%) | catalogued as rs867337533; called by muse, mutect2, varscan2
- IGSF10 | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 250/460 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1365109350; called by muse, mutect2, varscan2
- IHO1 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 345/581 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs1179321798; called by muse, mutect2, varscan2
- IL27RA | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 256/363 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.092); catalogued as COSV54600233; called by muse, mutect2, varscan2
- IL2RB | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 306/523 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV53425048; called by muse, mutect2, varscan2
- IL36A | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 180/306 reads (59%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs866220179, COSV52082919; called by muse, mutect2, varscan2
- IL36B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs755811144, COSV52084410; called by muse, mutect2, varscan2
- INHBC | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 252/431 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.419); catalogued as rs1470332298; called by muse, mutect2, varscan2
- INTS6L | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 104/391 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1177830333; called by muse, varscan2
- IQCA1 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99609400; called by muse, mutect2, varscan2
- IQCH | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs780947039; called by muse, mutect2, varscan2
- IRGC | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 173/720 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764460673; called by muse, mutect2, varscan2
- ITGA1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 159/293 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140779034; called by muse, mutect2, varscan2
- ITGAX | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51646916; called by muse, mutect2, varscan2
- ITLN1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 194/352 reads (55%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100406260; called by muse, varscan2
- ITM2A | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64810927; called by muse, mutect2, varscan2
- IVL | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 170/446 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.581); catalogued as rs201971901; called by muse, mutect2, varscan2
- IVL | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 356/644 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.382); catalogued as rs541702541, COSV100908137; called by muse, varscan2
- IWS1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 146/452 reads (32%) | catalogued as COSV54870217; called by muse, mutect2, varscan2
- JAM2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 130/238 reads (55%) | catalogued as rs781476062; called by muse, mutect2, varscan2
- JCAD | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 337/342 reads (99%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as rs763764027, COSV64760999; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 113/351 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148623870; called by muse, mutect2, varscan2
- KALRN | c.7375G>A p.E2459K (on ENST00000360013 / NM_001024660.4; = p.E762K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/360 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.992); catalogued as COSV52262789; called by muse, mutect2, varscan2
- KANK4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 357/623 reads (57%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs201256809, COSV62985569; called by muse, mutect2, varscan2
- KCNB1 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 323/648 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV65567159; called by muse, mutect2, varscan2
- KCNH7 | c.2945G>A p.R982K | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100148690, COSV59797530; called by muse, mutect2, varscan2
- KCNJ15 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 273/596 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.156); catalogued as rs1227840730, COSV60811113; called by muse, mutect2
- KCNJ4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 265/442 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57859103; called by muse, mutect2, varscan2
- KCTD19 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 202/317 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as rs1210488903; called by muse, mutect2, varscan2
- KDM5B | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 192/482 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs765004569, COSV52506637, COSV52510135; called by muse, mutect2, varscan2
- KIAA0408 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 316/317 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772770879; called by muse, mutect2, varscan2
- KIAA1522 | c.1504G>A p.G502S (on ENST00000373480 / NM_001198972.2; = p.G561S on NM_020888.3) | Missense Mutation (SNP) | VAF 378/602 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs759839842; called by muse, mutect2, varscan2
- KIAA1614 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 296/673 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs575391757, COSV62551133; called by muse, mutect2, varscan2
- KIF20B | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 169/169 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767771862; called by muse, mutect2, varscan2
- KIRREL3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 116/404 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs755625697; called by muse, mutect2, varscan2
- KLK13 | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 186/428 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1209982241; called by muse, mutect2, varscan2
- KMT2D | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 293/449 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs199724002, COSV56409523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPNA5 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 173/173 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as rs147305551, COSV62652787; called by muse, mutect2, varscan2
- KRT10 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 454/456 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV54088142, COSV54088254; called by muse, mutect2, varscan2
- KRT26 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 199/435 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868550000; called by muse, mutect2, varscan2
- KRT33A | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 460/460 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs751294091; called by muse, mutect2, varscan2
- KRT6C | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 146/358 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as rs542254329; called by muse, varscan2
- KRTAP2-1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 303/787 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs1238572660, COSV101195354; called by muse, mutect2, varscan2
- KRTAP2-2 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 104/396 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs370400944; called by muse, varscan2
- KSR2 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 254/436 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100195027; called by muse, mutect2, varscan2
- KSR2 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 175/404 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV60368131; called by muse, mutect2, varscan2
- L1TD1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 114/336 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV63133709; called by muse, mutect2, varscan2
- LACRT | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as rs1455770578; called by muse, mutect2, varscan2
- LAMA1 | c.7078C>T p.R2360C | Missense Mutation (SNP) | VAF 149/339 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs765870262, COSV67534647; called by muse, mutect2, varscan2
- LAMA5 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 99/429 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.076); catalogued as rs748077073; called by muse, mutect2, varscan2
- LANCL2 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 136/311 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376130597; called by muse, mutect2, varscan2
- LCN9 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 173/373 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs373991789, COSV99479501; called by muse, mutect2, varscan2
- LEPR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 200/535 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267598694, COSV62747060; called by muse, mutect2, varscan2
- LGSN | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 257/258 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1040530696; called by muse, mutect2, varscan2
- LHCGR | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 144/402 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs149917479, COSV54297069; called by muse, mutect2, varscan2
- LILRB2 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 363/756 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV58747468; called by muse, mutect2, varscan2
- LIN54 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100464552; called by muse, mutect2, varscan2
- LIN7A | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 169/297 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV54024589; called by muse, varscan2
- LINGO2 | c.308A>C p.N103T | Missense Mutation (SNP) | VAF 255/514 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs376791650; called by muse, mutect2, varscan2
- LRP1B | c.10082G>A p.R3361Q | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV67196916, COSV67285422; called by muse, varscan2
- LRRC40 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 162/424 reads (38%) | catalogued as rs1042273638; called by muse, mutect2, varscan2
- LRRC55 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 166/489 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs374511641, COSV73006823; called by muse, mutect2, varscan2
- LRRC7 | c.877C>T p.L293F (on ENST00000651989 / NM_001370785.2; = p.L260F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 242/425 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50466301; called by muse, mutect2, varscan2
- LUM | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 234/386 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57127897; called by muse, mutect2, varscan2
- LYPD4 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 141/533 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs782199915, COSV58028284; called by muse, mutect2, varscan2
- MAGEA11 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 313/474 reads (66%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.631); catalogued as rs1557362407; called by muse, mutect2, varscan2
- MAGEC1 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 378/615 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs748918214; called by muse, varscan2
- MAGEC1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 370/674 reads (55%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.968); catalogued as COSV53579808; called by muse, mutect2, varscan2
- MAGEC1 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 371/524 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs867630448; called by muse, mutect2, varscan2
- MAGEE1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 100/472 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV63910436; called by muse, varscan2
- MAGI2 | c.3450G>A p.M1150I | Missense Mutation (SNP) | VAF 181/396 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1563153542, COSV62684224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MALRD1 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs1338072414; called by muse, mutect2, varscan2
- MAP1A | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 252/361 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55808448; called by muse, mutect2, varscan2
- MAP3K14 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 418/418 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767382383; called by muse, mutect2, varscan2
- MAP4K5 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 103/226 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1255887449; called by muse, mutect2, varscan2
- MARCHF2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 150/229 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.435); catalogued as rs375503291; called by muse, mutect2, varscan2
- MEGF6 | c.2893G>A p.G965R | Missense Mutation (SNP) | VAF 252/520 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs779065913; called by muse, varscan2
- METTL11B | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 161/299 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV63030129; called by muse, mutect2, varscan2
- MFRP | c.422G>A p.R141Q (on ENST00000449574; = p.R517Q on NM_031433.4) | Missense Mutation (SNP) | VAF 118/370 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs767870051; called by muse, mutect2, varscan2
- MISP | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 126/400 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV53121970; called by muse, mutect2, varscan2
- MLKL | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 100/326 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV58206086; called by muse, mutect2, varscan2
- MMP15 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.607); catalogued as rs141624298; called by muse, mutect2, varscan2
- MMP8 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 49/185 reads (26%) | catalogued as rs1273485096; called by muse, mutect2, varscan2
- MMRN2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.289); catalogued as rs762579403; called by muse, mutect2, varscan2
- MMUT | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 452/723 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs769922244, CM060368, CM060370, COSV51286554; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1767A>G p.I589M | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.322); catalogued as rs747877316; called by muse, mutect2, varscan2
- MROH2B | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 154/389 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV101270807; called by muse, mutect2, varscan2
- MROH2B | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 184/340 reads (54%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.115); catalogued as rs868730638, COSV68189234; called by muse, mutect2, varscan2
- MS4A8 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100282522; called by muse, mutect2, varscan2
- MSH3 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 136/376 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs199659527, COSV54146901; ClinVar: uncertain significance; called by muse, varscan2
- MSR1 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 132/311 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50523234; called by muse, mutect2, varscan2
- MTNR1B | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 91/307 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57065305; called by muse, mutect2, varscan2
- MTRES1 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 238/239 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV100261239; called by muse, mutect2, varscan2
- MUC12 | c.10342C>T p.P3448S (on ENST00000379442; = p.P3305S on NM_001164462.1) | Missense Mutation (SNP) | VAF 309/5314 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs1374203028; called by muse, mutect2
- MUC16 | c.29965C>T p.P9989S | Missense Mutation (SNP) | VAF 201/316 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs866730767; called by muse, mutect2, varscan2
- MUC16 | c.28658C>T p.S9553F | Missense Mutation (SNP) | VAF 123/373 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as rs751932910; called by muse, mutect2, varscan2
- MUC16 | c.11938C>T p.P3980S | Missense Mutation (SNP) | VAF 249/378 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs761414131; called by muse, mutect2, varscan2
- MUC16 | c.11140C>T p.H3714Y | Missense Mutation (SNP) | VAF 158/261 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs867039375, COSV67487590; called by muse, mutect2, varscan2
- MUC16 | c.9587C>T p.S3196F | Missense Mutation (SNP) | VAF 106/177 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs750830815; called by muse, mutect2, varscan2
- MUC16 | c.9545C>T p.P3182L | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.254); catalogued as COSV101198527, COSV67465828; called by muse, mutect2, varscan2
- MUC3A | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 356/692 reads (51%) | SIFT deleterious, low confidence (0.01); catalogued as rs759978968; called by muse, mutect2, varscan2
- MUC5AC | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 162/478 reads (34%) | SIFT deleterious (0); catalogued as rs902560168; called by muse, mutect2, varscan2
- MYH1 | c.2395T>C p.F799L | Missense Mutation (SNP) | VAF 234/349 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs1407451831; called by muse, mutect2, varscan2
- MYH15 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 161/395 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56316451; called by muse, mutect2, varscan2
- MYH4 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as rs371573424; called by muse, mutect2, varscan2
- MYH8 | c.5480G>A p.G1827E | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV67963082, COSV67963478; called by muse, mutect2, varscan2
- MYLK | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 260/466 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60605014; called by muse, mutect2, varscan2
- MYO16 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as rs868261824, COSV51781539; called by muse, mutect2, varscan2
- MYO3A | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.15); catalogued as COSV56334984, COSV56352401; called by muse, mutect2, varscan2
- MYO5B | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 138/308 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs993447719; called by muse, mutect2, varscan2
- MYOM2 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 151/329 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50745884, COSV50796799; called by muse, mutect2, varscan2
- MYOM2 | c.3049C>A p.P1017T | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50763818; called by muse, mutect2, varscan2
- NADSYN1 | c.1687C>G p.L563V | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100034346; called by muse, mutect2, varscan2
- NADSYN1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 106/374 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100035022; called by muse, mutect2, varscan2
- NALCN | c.4139C>T p.T1380I | Missense Mutation (SNP) | VAF 180/288 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV51944342; called by muse, mutect2, varscan2
- NARS2 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 154/243 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481123553, COSV55249884; called by muse, mutect2, varscan2
- NASP | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs896757778, COSV63111970; called by muse, mutect2
- NAV2 | c.4192C>T p.H1398Y (on ENST00000396087 / NM_001244963.2; = p.H1375Y on NM_145117.5) | Missense Mutation (SNP) | VAF 320/466 reads (69%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs1194398058; called by muse, mutect2, varscan2
- NCKAP1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1184998419, COSV62943970; called by muse, mutect2, varscan2
- NEB | c.15776G>A p.W5259* | Nonsense Mutation (SNP) | VAF 105/353 reads (30%) | catalogued as COSV50806836; called by muse, varscan2
- NELL2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 150/275 reads (55%) | catalogued as COSV61576934; called by muse, mutect2, varscan2
- NEXMIF | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 206/560 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV50080191; called by muse, mutect2, varscan2
- NF1 | c.3975-1G>A p.X1325_splice | Splice Site (SNP) | VAF 180/180 reads (100%) | catalogued as CS153440, COSV100647043, COSV62200559; called by muse, mutect2, varscan2
- NF1 | c.3975G>A p.R1325= | Splice Region (SNP) | VAF 185/185 reads (100%) | catalogued as COSV62192944; called by muse, mutect2, varscan2
- NFAM1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 160/417 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs150375095; called by muse, mutect2, varscan2
- NFE2L1 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 563/563 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1428181976; called by muse, mutect2, varscan2
- NGLY1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 235/414 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99770413; called by muse, mutect2, varscan2
- NIFK | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 128/204 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs761077196, COSV53534615; called by muse, mutect2, varscan2
- NINL | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 215/401 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs759264606; called by muse, mutect2
- NLRP3 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 258/589 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1475824860, COSV100276559, COSV60220608; called by muse, mutect2, varscan2
- NLRP4 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 139/324 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV56723100; called by muse, mutect2, varscan2
- NOBOX | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769328958, COSV56192923; called by muse, mutect2, varscan2
- NOTCH4 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 257/743 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs1041838804; called by muse, mutect2, varscan2
- NOX1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 178/272 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs865995944, COSV99471785; called by muse, mutect2, varscan2
- NRG3 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV64562880; called by muse, mutect2, varscan2
- NRK | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 311/499 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs372847875, COSV99686720; called by muse, mutect2, varscan2
- NRXN3 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 218/518 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs1203264894; called by muse, mutect2, varscan2
- NSD1 | c.7595C>T p.S2532L | Missense Mutation (SNP) | VAF 254/448 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV61779603; called by muse, mutect2, varscan2
- NT5C1B | c.934C>T p.L312F (on ENST00000359846 / NM_001199086.2; = p.L252F on NM_033253.4) | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV58399655; called by muse, mutect2, varscan2
- NUGGC | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 153/308 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs374292249; called by muse, mutect2, varscan2
- NUTM2F | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 156/371 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.191); catalogued as rs1323216273; called by muse, mutect2, varscan2
- NXPH2 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 137/389 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55645923; called by muse, mutect2, varscan2
- NYAP1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 287/564 reads (51%) | catalogued as COSV55723198; called by muse, varscan2
- NYAP1 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 270/562 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs143758472, COSV55720544; called by muse, varscan2
- OBP2A | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 146/334 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.46); catalogued as rs775504301, COSV59790985; called by muse, mutect2
- OCSTAMP | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 269/511 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV54098816; called by muse, mutect2, varscan2
- OOSP2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 130/221 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140171460, COSV53928347, COSV99613480; called by muse, mutect2, varscan2
- OPTC | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 249/570 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100921850; called by muse, mutect2, varscan2
- OR10A5 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 150/244 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs750209370, COSV55053347; called by muse, mutect2, varscan2
- OR10H5 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 337/515 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.337); catalogued as rs575365825, COSV58277696; called by muse, mutect2, varscan2
- OR10Q1 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 276/416 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.118); catalogued as COSV57471788; called by muse, mutect2, varscan2
- OR13C8 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 152/296 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs867329527, COSV58611239; called by muse, mutect2, varscan2
- OR14A16 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 266/515 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs866940782, COSV62926444; called by muse, mutect2, varscan2
- OR1F1 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 98/304 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs953195042; called by muse, mutect2, varscan2
- OR1Q1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 222/478 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs144709927, COSV52918475; called by muse, mutect2, varscan2
- OR2AE1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 266/523 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs905385422; called by muse, mutect2, varscan2
- OR2G2 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 293/622 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60740372; called by muse, mutect2, varscan2
- OR2G6 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 292/623 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV100598017; called by muse, mutect2, varscan2
- OR2J1 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 315/908 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749161186; called by muse, mutect2, varscan2
- OR2M5 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 334/718 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs139017053; called by muse, varscan2
- OR2T3 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 126/154 reads (82%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs1425555169; called by mutect2, varscan2
- OR2T33 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 295/862 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58818332; called by muse, mutect2, varscan2
- OR2T33 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 401/891 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100532328, COSV58816478; called by muse, mutect2, varscan2
- OR4E2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 268/617 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs866396121, COSV57731749; called by muse, mutect2, varscan2
- OR51B5 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 152/246 reads (62%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV56175038; called by muse, mutect2, varscan2
- OR51F1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 248/408 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs369623823; called by muse, mutect2
- OR51G1 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 101/353 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1284781185; called by muse, mutect2, varscan2
- OR52E4 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 268/395 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as rs144620167; called by muse, mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 234/336 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- OR52L1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 259/389 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs867894367, COSV59985811; called by muse, mutect2, varscan2
- OR52N1 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 140/396 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1403316614, COSV57692994; called by muse, mutect2, varscan2
- OR5H1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 247/484 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs200751012; called by muse, mutect2, varscan2
- OR5H14 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 261/452 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs370923244; called by muse, mutect2, varscan2
- OR5L2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 263/425 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445768587; called by muse, mutect2, varscan2
- OR5M1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV73202117; called by muse, mutect2, varscan2
- OR6C65 | c.874A>G p.N292D | Missense Mutation (SNP) | VAF 146/262 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV101110203; called by muse, mutect2, varscan2
- OR8B2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 102/342 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66664714; called by muse, mutect2
- OR8D1 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 117/173 reads (68%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV63442247; called by muse, mutect2, varscan2
- OR8J3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 80/116 reads (69%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV56880208, COSV56883621; called by muse, mutect2, varscan2
- OR8K3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 241/385 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as rs767024951; called by muse, mutect2, varscan2
- OR9Q1 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV59044366; called by muse, mutect2, varscan2
- ORAI2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 256/532 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1198195830; called by muse, mutect2, varscan2
- OTOG | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as rs774229562; called by muse, mutect2, varscan2
- OTOG | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61129789; called by muse, mutect2, varscan2
- OTOG | c.7567C>T p.H2523Y | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1314439748; called by muse, mutect2, varscan2
- OTOGL | c.6041C>T p.P2014L (on ENST00000547103; = p.P2005L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 143/258 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV54023488; called by muse, mutect2, varscan2
- PAM | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 115/316 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs371136481; called by muse, mutect2, varscan2
- PAPPA | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 168/342 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs142893148, COSV60294044; called by muse, mutect2, varscan2
- PAPPA2 | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 229/420 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62790680; called by muse, mutect2, varscan2
- PAQR4 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 195/576 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs566373345, COSV99234321; called by muse, mutect2, varscan2
- PATJ | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 283/745 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1278118763; called by muse, mutect2, varscan2
- PAX8 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 215/319 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54511538; called by muse, mutect2, varscan2
- PCDHA1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 292/503 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65375119; called by muse, mutect2, varscan2
- PCDHA2 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 366/653 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65368946; called by muse, mutect2, varscan2
- PCDHA3 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 168/290 reads (58%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV65364477; called by mutect2, varscan2
- PCDHA5 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 390/705 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV65353988; called by muse, mutect2, varscan2
- PCDHA8 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 165/170 reads (97%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV65334627; called by muse, mutect2, varscan2
- PCDHB15 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 189/671 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1307688694; called by muse, mutect2, varscan2
- PCDHB5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 163/391 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as COSV50647190; called by muse, mutect2, varscan2
- PCDHB5 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 223/371 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs1554275831, COSV50649076; called by muse, mutect2, varscan2
- PCDHGA7 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 102/411 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.314); catalogued as rs1046340065, COSV53927958; called by muse, mutect2, varscan2
- PCLO | c.12611C>T p.S4204L | Missense Mutation (SNP) | VAF 181/382 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61617546; called by muse, mutect2, varscan2
- PCLO | c.12391G>A p.E4131K | Missense Mutation (SNP) | VAF 162/364 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61640605; called by muse, mutect2, varscan2
- PCLO | c.10219G>A p.E3407K | Missense Mutation (SNP) | VAF 298/550 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs1282303356, COSV61621336; called by muse, mutect2, varscan2
- PCLO | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 240/484 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs200555866; called by muse, varscan2
- PCLO | c.3359G>A p.G1120E | Missense Mutation (SNP) | VAF 217/431 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV61652677; called by muse, mutect2, varscan2
- PDE1A | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 111/168 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs747334904, COSV59513247; called by muse, mutect2, varscan2
- PDGFRA | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 164/166 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57265331; called by muse, mutect2, varscan2
- PDHA2 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV54781493; called by muse, mutect2, varscan2
- PDS5A | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs767207351; called by muse, mutect2, varscan2
- PDZD7 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148695069, CM1513240, COSV64646209; called by muse, mutect2, varscan2
- PERCC1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 286/464 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs533187594; called by muse, varscan2
- PGAP6 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 94/288 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs748656747, COSV51739334, COSV51741491; called by muse, mutect2, varscan2
- PHLPP1 | c.4375C>T p.R1459W | Missense Mutation (SNP) | VAF 259/515 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as rs759804178; called by muse, mutect2, varscan2
- PHRF1 | c.4622C>T p.S1541L (on ENST00000264555 / NM_001286581.2; = p.S1540L on NM_020901.4) | Missense Mutation (SNP) | VAF 190/568 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as rs368798093; called by muse, mutect2, varscan2
- PIEZO2 | c.7069G>A p.D2357N | Missense Mutation (SNP) | VAF 213/431 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1474217845, COSV99554996; called by muse, mutect2, varscan2
- PIK3R4 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 165/470 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.079); catalogued as COSV63244219; called by muse, mutect2, varscan2
- PKD1L3 | c.5036G>A p.G1679E | Missense Mutation (SNP) | VAF 177/240 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100324677; called by muse, mutect2, varscan2
- PLA2G4E | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868610633; called by muse, mutect2, varscan2
- PLB1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 108/367 reads (29%) | catalogued as rs369610326; called by muse, mutect2, varscan2
- PLCB2 | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 169/517 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs750702293, COSV53031961; called by muse, mutect2, varscan2
- PLCB4 | c.2982G>A p.M994I | Missense Mutation (SNP) | VAF 133/333 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753931051, COSV53798516; called by muse, mutect2, varscan2
- PLCE1 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 263/263 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs754397478, COSV53376651; called by muse, mutect2, varscan2
- PLCH1 | c.2830G>A p.D944N (on ENST00000340059 / NM_001130960.2; = p.D936N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 215/439 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV58189158; called by muse, mutect2, varscan2
- PLCH2 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 188/569 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs771815726; called by muse, mutect2, varscan2
- PLCZ1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV99855703; called by muse, mutect2, varscan2
- PLD1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs745380460; called by muse, mutect2, varscan2
- PLD5 | c.1064C>T p.T355I (on ENST00000442594; = p.T293I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/325 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as COSV100138889; called by muse, mutect2, varscan2
- PLEKHA7 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 103/307 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60580513; called by muse, mutect2, varscan2
- PLEKHG6 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 296/296 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV50600093; called by muse, mutect2, varscan2
- PMFBP1 | c.1783C>T p.R595C (on ENST00000537465; = p.R590C on NM_031293.3) | Missense Mutation (SNP) | VAF 132/211 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs149578677, COSV99401367; called by muse, mutect2, varscan2
- PODN | c.274G>A p.E92K (on ENST00000395871; = p.E44K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 349/727 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs769165495, COSV57010995; called by muse, mutect2, varscan2
- POF1B | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 224/370 reads (61%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as COSV53137868; called by muse, mutect2, varscan2
- POLE | c.6058C>T p.P2020S | Missense Mutation (SNP) | VAF 243/401 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV57692027; called by muse, mutect2, varscan2
- POLE | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 167/328 reads (51%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.566); catalogued as COSV57693443; called by muse, mutect2, varscan2
- POLI | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54191689; called by muse, mutect2, varscan2
- POLI | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371876172; called by muse, mutect2, varscan2
- POLR1A | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 200/321 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55691483; called by muse, mutect2, varscan2
- POLRMT | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV73933405; called by muse, mutect2, varscan2
- POM121L12 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 278/584 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as rs750523098, COSV101375017; called by muse, mutect2, varscan2
- POTEF | c.2229G>A p.M743I | Missense Mutation (SNP) | VAF 86/702 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV62543084; called by muse, mutect2
- POTEG | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 115/526 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs758824790; called by muse, varscan2
- POTEG | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 373/1706 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs753239019, COSV101611941; called by muse, mutect2, varscan2
- POU3F1 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 224/346 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); catalogued as rs1291000847; called by muse, varscan2
- POU6F2 | c.885G>A p.Q295= | Splice Region (SNP) | VAF 187/388 reads (48%) | catalogued as COSV68878060; called by muse, mutect2, varscan2
- PPFIA2 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs550703985; called by muse, varscan2
- PPP1R2C | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs1173919536, COSV65364021; called by muse, mutect2, varscan2
- PPP2R3A | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 221/401 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.201); catalogued as COSV53872344; called by muse, mutect2, varscan2
- PRAMEF12 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 202/418 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100742977, COSV100743171; called by muse, mutect2, varscan2
- PRAMEF17 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 117/346 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs989031993; called by muse, varscan2
- PRG4 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 262/700 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs771143941, COSV63354989; called by mutect2, varscan2
- PRH1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 176/466 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV101457518; called by muse, varscan2
- PRKAA2 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 189/393 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409708472, COSV100982756; called by muse, mutect2, varscan2
- PRKACG | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 221/475 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55240892; called by muse, mutect2, varscan2
- PRKD2 | c.1009A>G p.K337E | Missense Mutation (SNP) | VAF 303/580 reads (52%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.953); catalogued as rs779171577; called by muse, mutect2, varscan2
- PRND | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 288/577 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.823); catalogued as rs571957668, COSV99045316; called by muse, mutect2, varscan2
- PROS1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373983977, CM064172, COSV67777518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRT4 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 279/558 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as rs752145973; called by muse, mutect2, varscan2
- PRUNE2 | c.7493G>A p.G2498E | Missense Mutation (SNP) | VAF 125/249 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65043002; called by muse, mutect2, varscan2
- PRUNE2 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 236/490 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV65042174; called by muse, mutect2, varscan2
- PTCHD4 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 184/516 reads (36%) | catalogued as rs753250425; called by muse, mutect2, varscan2
- PTEN | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 215/258 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64289137; called by muse, mutect2, varscan2
- PTF1A | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 180/286 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1038493023; called by muse, mutect2, varscan2
- PTPRB | c.5756G>A p.R1919Q | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200824991; called by muse, mutect2, varscan2
- PTPRB | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 131/223 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs750869262, COSV54239121; called by muse, mutect2, varscan2
- PTPRD | c.3876G>A p.R1292= | Splice Region (SNP) | VAF 119/300 reads (40%) | catalogued as rs1015998828; called by muse, mutect2, varscan2
- PTPRN2 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 266/516 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67039045; called by muse, mutect2
- PTPRR | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV51731015; called by muse, mutect2, varscan2
- PTPRR | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 105/288 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144153905; called by muse, mutect2, varscan2
- PTPRT | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 258/541 reads (48%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.995); catalogued as COSV61987668, COSV62010614; called by muse, mutect2, varscan2
- PTX4 | c.1174G>A p.G392S (on ENST00000447419 / NM_001328608.2; = p.G387S on NM_001013658.1) | Missense Mutation (SNP) | VAF 134/433 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs758849133; called by muse, mutect2, varscan2
- PXDNL | c.2990T>C p.V997A | Missense Mutation (SNP) | VAF 213/439 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs536430275, COSV62501827; called by muse, mutect2, varscan2
- PZP | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.196); catalogued as rs771108767; called by muse, mutect2, varscan2
- QSER1 | c.1999C>T p.P667S (on ENST00000399302; = p.P796S on NM_001076786.3) | Missense Mutation (SNP) | VAF 132/211 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768155722; called by muse, mutect2, varscan2
- RALGAPA2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as rs1287668959; called by muse, mutect2, varscan2
- RBM25 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 232/415 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1294642356, COSV56199734; called by muse, mutect2, varscan2
- RBP4 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 307/308 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs766365350, COSV65159613; called by muse, mutect2, varscan2
- RCE1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 219/340 reads (64%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs775687215; called by muse, mutect2, varscan2
- RCSD1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 247/569 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750952554, COSV63257970; called by muse, mutect2, varscan2
- RECQL4 | c.2463+1G>T p.X821_splice | Splice Site (SNP) | VAF 54/288 reads (19%) | catalogued as COSV99467365; called by mutect2, varscan2
- RECQL4 | c.2463G>A p.Q821= | Splice Region (SNP) | VAF 59/345 reads (17%) | catalogued as rs1447984125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS6 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 158/426 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667013; called by muse, mutect2, varscan2
- RGS7BP | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.806); catalogued as rs151111266; called by muse, mutect2, varscan2
- RHOT2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 237/363 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1175144692; called by muse, mutect2, varscan2
- RIMS2 | c.2425C>T p.R809W (on ENST00000666250 / NM_001348490.2; = p.R617W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 203/418 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556481632, COSV99180199; called by muse, mutect2, varscan2
- RIMS2 | c.4110A>T p.E1370D (on ENST00000666250 / NM_001348490.2; = p.E941D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 211/399 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51669480; called by muse, mutect2, varscan2
- RIPOR3 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 318/643 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.271); catalogued as rs969301387; called by muse, varscan2
- RNASE2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 293/540 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV58941672; called by muse, mutect2, varscan2
- RNF128 | c.797G>A p.G266E (on ENST00000255499 / NM_194463.2; = p.G240E on NM_024539.3) | Missense Mutation (SNP) | VAF 110/313 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV55253331; called by muse, mutect2, varscan2
- RNF128 | c.916C>T p.P306S (on ENST00000255499 / NM_194463.2; = p.P280S on NM_024539.3) | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs771248841; called by muse, mutect2, varscan2
- ROBO2 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 201/335 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as rs372913645; called by muse, mutect2, varscan2
- ROBO2 | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 326/584 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.073); catalogued as COSV59936464; called by muse, mutect2, varscan2
- ROPN1L | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 173/429 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV56874362; called by muse, mutect2, varscan2
- RP1 | c.5020G>A p.D1674N | Missense Mutation (SNP) | VAF 172/356 reads (48%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.462); catalogued as COSV55126970; called by muse, mutect2, varscan2
- RP1L1 | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 285/512 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs1339683035; called by muse, mutect2, varscan2
- RP1L1 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 243/545 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as COSV101223369; called by muse, varscan2
- RSBN1 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 291/497 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54731075; called by muse, mutect2, varscan2
- RSPH6A | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 326/662 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55574083; called by muse, mutect2, varscan2
- RTL3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 312/500 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs754780962, COSV100329782, COSV58183264; called by muse, mutect2, varscan2
- RYR1 | c.7210G>A p.E2404K | Missense Mutation (SNP) | VAF 233/437 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.27); catalogued as rs111364296, CM091767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.9020A>G p.N3007S | Missense Mutation (SNP) | VAF 84/373 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1263831859; called by muse, mutect2, varscan2
- RYR1 | c.11090C>T p.P3697L | Missense Mutation (SNP) | VAF 178/368 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1396944765, COSV62098729; called by muse, varscan2
- SALL1 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 263/401 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as COSV51765791; called by muse, mutect2, varscan2
- SAMD9 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 198/418 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1159455564; called by muse, mutect2, varscan2
- SAV1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 302/522 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs757631264; called by muse, mutect2, varscan2
- SBF1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 193/442 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62371027; called by muse, mutect2, varscan2
- SBSN | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 289/611 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101510040; called by muse, mutect2, varscan2
- SCARA5 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 210/426 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs752998049, COSV61572090, COSV61574497; called by muse, mutect2, varscan2
- SCGB3A2 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 160/386 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV57023891; called by muse, mutect2, varscan2
- SCN11A | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 172/289 reads (60%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1403716541, COSV56565083; called by muse, mutect2, varscan2
- SCN11A | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 154/409 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56571409; called by muse, mutect2, varscan2
- SCN11A | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 136/464 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs1191368962, COSV100181967; called by muse, varscan2
- SCN1A | c.5735G>A p.R1912Q (on ENST00000303395 / NM_001202435.3; = p.R1901Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/317 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs373896263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 317/317 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV71125897; called by muse, mutect2, varscan2
- SCN5A | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 277/503 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.836); catalogued as COSV61116597; called by muse, mutect2, varscan2
- SCUBE1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 176/447 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as rs780067935, COSV62611441; called by muse, mutect2, varscan2
- SDHA | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 111/288 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.031); catalogued as COSV53766318, COSV53770526; called by muse, mutect2, varscan2
- SEMA3A | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 148/299 reads (49%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.814); catalogued as rs1487309678; called by muse, mutect2, varscan2
- SERPINI2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 100/304 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217333684; called by muse, mutect2
- SETD1B | c.4760C>T p.P1587L | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1419095887, COSV57354738; called by muse, mutect2, varscan2
- SFPQ | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 222/342 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100599470; called by muse, mutect2, varscan2
- SGCZ | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 125/290 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601802, COSV65998392, COSV66047381; called by muse, mutect2, varscan2
- SH2B3 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 305/548 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs933970612; called by muse, mutect2, varscan2
- SHANK2 | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 110/301 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV99576785; called by muse, mutect2, varscan2
- SHISA9 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 179/263 reads (68%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as COSV69633146, COSV69644113; called by muse, mutect2, varscan2
- SHISA9 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 348/516 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as rs1436328307; called by muse, mutect2, varscan2
- SIGLEC11 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 383/763 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.411); catalogued as rs550434699, COSV70221929; called by muse, mutect2, varscan2
- SIRPB1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54374122; called by muse, mutect2
- SLAMF8 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 250/577 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs868712155; called by muse, mutect2, varscan2
- SLC12A3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 227/357 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs780461639, CM121286; called by muse, mutect2, varscan2
- SLC17A1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 160/510 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752970228, COSV99766086; called by muse, mutect2, varscan2
- SLC17A3 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 85/466 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs146416795; called by muse, mutect2, varscan2
- SLC17A6 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 187/463 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV99581498; called by muse, mutect2, varscan2
- SLC22A24 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 160/242 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1208836445; called by muse, mutect2, varscan2
- SLC26A6 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 192/451 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56571293; called by muse, mutect2, varscan2
- SLC27A6 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 97/362 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52488856; called by muse, mutect2, varscan2
- SLC2A14 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 216/218 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746537796; called by muse, mutect2, varscan2
- SLC2A14 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 214/216 reads (99%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs780109041, COSV61586144, COSV61588360; called by muse, mutect2, varscan2
- SLC30A3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 79/242 reads (33%) | catalogued as COSV51988263; called by muse, mutect2, varscan2
- SLC35A4 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 195/432 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.164); catalogued as rs1488503931; called by muse, mutect2, varscan2
- SLC38A1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 143/239 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV67063435; called by muse, mutect2, varscan2
- SLC38A4 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 109/284 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56964769; called by muse, mutect2, varscan2
- SLC38A4 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 155/285 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56964792; called by muse, mutect2, varscan2
- SLC38A5 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 274/276 reads (99%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as COSV58335440; called by muse, mutect2, varscan2
- SLC39A6 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 133/301 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52368024; called by muse, mutect2, varscan2
- SLC5A4 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 161/280 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs780445431, COSV99832085; called by muse, mutect2, varscan2
- SLC6A1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 122/355 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55116273; called by muse, varscan2
- SLC6A17 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 429/737 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs141398428; called by muse, mutect2, varscan2
- SLC6A8 | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 130/466 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99466266; called by muse, mutect2, varscan2
- SLC8A3 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 214/438 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373933717; called by muse, mutect2, varscan2
- SLC9C1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV59885674; called by muse, mutect2, varscan2
- SLC9C1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs749177716, COSV59886093; called by muse, mutect2, varscan2
- SLX4IP | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs755713479, COSV57947634; called by muse, mutect2, varscan2
- SMC1B | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 125/338 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as rs1162326927; called by muse, mutect2, varscan2
- SNAPC4 | c.3374C>T p.P1125L | Missense Mutation (SNP) | VAF 308/612 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as rs777913079; called by muse, varscan2
- SNCAIP | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 195/369 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54404148; called by muse, mutect2, varscan2
- SNCAIP | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 210/344 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV54403378; called by muse, mutect2, varscan2
- SNCAIP | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 131/354 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs773604913, COSV54403432; called by muse, mutect2, varscan2
- SOGA1 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 135/316 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs181256903, COSV52922181; called by muse, mutect2, varscan2
- SORCS3 | c.2591G>A p.G864E | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63793627; called by muse, mutect2, varscan2
- SORL1 | c.1713G>A p.W571* | Nonsense Mutation (SNP) | VAF 102/279 reads (37%) | catalogued as COSV52752740; called by muse, mutect2, varscan2
- SORL1 | c.4210G>A p.G1404R | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.489); catalogued as rs1451714828; called by muse, varscan2
- SOX14 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 279/616 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV60162738; called by muse, mutect2, varscan2
- SPAM1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 221/458 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV56141005; called by muse, mutect2, varscan2
- SPATA4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54589530; called by muse, mutect2, varscan2
- SPDYE5 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 203/463 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1554483405; called by muse, mutect2, varscan2
- SPTA1 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 196/392 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV63754117, COSV63759555; called by muse, mutect2, varscan2
- SPTBN4 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 234/471 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1488394403; called by muse, mutect2, varscan2
- SRCAP | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 276/421 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV99349878; called by muse, mutect2, varscan2
- SRGAP3 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 137/406 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV64530320; called by muse, mutect2, varscan2
- SRMS | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 172/638 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs56053583; called by muse, mutect2, varscan2
- SRRM4 | c.1763_1786del p.R588_S595del | In Frame Del (DEL) | VAF 176/442 reads (40%) | catalogued as rs778154280; called by mutect2, varscan2
- SRSF11 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 201/438 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs750684163; called by muse, mutect2, varscan2
- SRSF2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 272/560 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as COSV57971542; called by muse, varscan2
- SSC5D | c.4031C>T p.S1344F | Missense Mutation (SNP) | VAF 327/685 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs865785650; called by muse, mutect2, varscan2
2,132 further variants in this file (1,023 protein-altering or splice-affecting, 994 silent, 115 other) are not listed here.
